CCDI case PBBWUG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Base of tongue.
https://portal.gdc.cancer.gov/cases/41406713-a52a-4b82-8b1d-8aed9a0c2513

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Base of tongue, NOS; Age at diagnosis: 4.3 years (1,563 days).

Biospecimens (3 samples)
- Sample 0DK1V3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK1W9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DK1WG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
